CCDI case PBCPYZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/29a0335e-9e45-4e6f-974e-1a8bcfc3a047

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 8.5 years (3,122 days).

Biospecimens (2 samples)
- Sample 0DX5C9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX5CB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
